FM case AD14666 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/3886665c-f3da-4c47-bd6d-338152ecf5d7

Female, 64.0 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
